Somatic mutation profile of tumor specimen 0DMWTW from CCDI case PBCBBP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.1 years (6,239 days).
Specimen 0DMWTW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26296925-c67d-4f3a-a1c7-e2b9daf56aff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMWU3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/243e74d4-50f3-4a16-95e4-faf0c614668c

The open-access MAF lists 37 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 10, 3'UTR 2, Intron 1, Frame Shift Del 1, 5'UTR 1, Nonsense Mutation 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 134/136 reads (99%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.3493A>G p.I1165V (on ENST00000506720 / NM_001322402.2; = p.I1097V on NM_015236.6) | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as rs1319618194; called by muse, mutect2
- CCDC18 | c.3760G>A p.E1254K (on ENST00000343253 / NM_001306076.1; = p.E1255K on NM_206886.4) | Missense Mutation (SNP) | VAF 150/698 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.805); catalogued as rs374437948; called by muse, mutect2, varscan2
- DOCK1 | c.3803C>T p.T1268M | Missense Mutation (SNP) | VAF 98/191 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs994557124; called by muse, mutect2, varscan2
- GSTA1 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs201803852; called by muse, mutect2, varscan2
- MORC1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 84/521 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs759790452, COSV51713109; called by muse, mutect2, varscan2
- THEMIS | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 82/478 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64070718; called by mutect2, varscan2
- ADGB | c.3004T>C p.S1002P | Missense Mutation (SNP) | VAF 20/514 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2
- C19orf38 | c.163_165del p.G55del | In Frame Del (DEL) | VAF 75/151 reads (50%) | called by mutect2, pindel, varscan2
- CAB39L | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- CD7 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP3 | c.3569G>A p.R1190Q | Missense Mutation (SNP) | VAF 77/1385 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- DOCK8 | c.2229C>A p.F743L | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIF7 | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 80/418 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PHC3 | c.752C>G p.T251R (on ENST00000494943 / NM_001308116.2; = p.T263R on NM_024947.4) | Missense Mutation (SNP) | VAF 18/605 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2
- SALL3 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 19/462 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.041); called by muse, mutect2
- SLC16A6 | c.1330G>A p.V444M | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- TMEM176A | c.123del p.R43Gfs*17 | Frame Shift Del (DEL) | VAF 97/224 reads (43%) | called by mutect2, pindel, varscan2
- TNKS | c.2291A>G p.E764G | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2
- TTC6 | c.84G>A p.M28I (on ENST00000267368; = p.M1297I on NM_001310135.3) | Missense Mutation (SNP) | VAF 95/180 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC45B | c.1842G>T p.K614N | Missense Mutation (SNP) | VAF 115/214 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ZNF76 | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 99/394 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- BPI | c.90G>A p.A30= (on ENST00000262865; = p.A26= on NM_001725.3) | Silent (SNP) | VAF 88/437 reads (20%) | catalogued as rs774631868; called by muse, mutect2, varscan2
- DGKK | c.1215C>T p.N405= | Silent (SNP) | VAF 95/103 reads (92%) | catalogued as rs1557226825; called by muse, mutect2, varscan2
- DVL1 | c.1182A>G p.L394= | Silent (SNP) | VAF 26/758 reads (3%) | called by muse, mutect2
- GLT6D1 | c.639C>A p.T213= | Silent (SNP) | VAF 132/296 reads (45%) | catalogued as COSV65627177; called by muse, mutect2, varscan2
- KL | c.2754C>T p.N918= | Silent (SNP) | VAF 44/620 reads (7%) | catalogued as rs377184621; called by muse, mutect2
- LTBP2 | c.804G>A p.P268= | Silent (SNP) | VAF 51/499 reads (10%) | catalogued as rs139052892; called by muse, mutect2, varscan2
- MYH4 | c.2274C>T p.T758= | Silent (SNP) | VAF 88/163 reads (54%) | catalogued as rs1249823573, COSV99702064; called by muse, mutect2, varscan2
- PEG10 | c.954G>A p.A318= (on ENST00000482108 / NM_001040152.2; = p.G352R on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/235 reads (26%) | called by muse, mutect2, varscan2
- RET | c.1146G>A p.Q382= | Silent (SNP) | VAF 94/364 reads (26%) | catalogued as rs770637118; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM132C | c.2535C>T p.P845= | Silent (SNP) | VAF 154/291 reads (53%) | catalogued as rs748568622; called by muse, mutect2, varscan2
- ADGRE4P | n.108C>T | RNA (SNP) | VAF 16/75 reads (21%) | catalogued as rs1314876647; called by muse, mutect2, varscan2
- AP3B1 | c.2993-89dup | Intron (INS) | VAF 28/60 reads (47%) | called by mutect2, varscan2
- IRF8 | c.*4C>T | 3'UTR (SNP) | VAF 73/360 reads (20%) | catalogued as rs752738499, COSV51896867; called by muse, mutect2, varscan2
- PTPRO | c.-56G>A | 5'UTR (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- WBP1 | c.*31C>A | 3'UTR (SNP) | VAF 18/512 reads (4%) | called by muse, mutect2
